CCDI case PBCFTR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7dc252e8-9200-4586-90a5-2095ea4bea90

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Central neurocytoma: ICD-O-3 morphology code: 9506/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.0 years (6,933 days).

Biospecimens (3 samples)
- Sample 0DR537: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR53D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR53J: Tissue type: Tumor; Specimen type: Solid Tissue.
